Somatic mutation profile of tumor specimen TCGA-IB-AAUS-01A (aliquot TCGA-IB-AAUS-01A-12D-A38G-08) from TCGA case TCGA-IB-AAUS, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 84.0 years (30,684 days).
Specimen TCGA-IB-AAUS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eb00d5df-1a7c-4d0f-ae25-4ec66d70989e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IB-AAUS-10A (Blood Derived Normal), aliquot TCGA-IB-AAUS-10A-01D-A38J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7f11adb6-7025-4a63-b163-f98853ac959e

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTC31 | c.229C>T p.H77Y | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as COSV99282319; called by muse, mutect2
